Somatic mutation profile of tumor specimen TCGA-XF-AAME-01A (aliquot TCGA-XF-AAME-01A-12D-A42E-08) from TCGA case TCGA-XF-AAME, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 64.2 years (23,448 days).
Specimen TCGA-XF-AAME-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 701c99f8-32e3-4dde-9e16-3a5ca94cb556.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-XF-AAME-10A (Blood Derived Normal), aliquot TCGA-XF-AAME-10A-01D-A42H-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d02b14ee-6098-4218-aa12-d25ec39a9738

The open-access MAF lists 15 somatic variants for this specimen: 14 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 13, Splice Site 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARPIN | c.301+1G>A p.X101_splice | Splice Site (SNP) | VAF 4/23 reads (17%) | catalogued as COSV100673467; called by muse, mutect2
- ATM | c.967A>G p.I323V | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.273); catalogued as rs587781511, CM000651, COSV53761273; ClinVar: conflicting interpretations of pathogenicity / likely pathogenic; called by muse, mutect2, varscan2
- CDK12 | c.2672C>T p.P891L | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV101420501; called by muse, mutect2
- DIAPH2 | c.851T>G p.I284S | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV61283343; called by muse, mutect2
- DPP3 | c.2023C>G p.P675A | Missense Mutation (SNP) | VAF 5/63 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV64757467; called by muse, mutect2
- ELSPBP1 | c.364G>A p.G122R | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.418); catalogued as COSV60414499; called by muse, mutect2, varscan2
- FERMT3 | c.1823A>C p.Q608P (on ENST00000279227 / NM_178443.3; = p.Q604P on NM_031471.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV54174945; called by muse, mutect2, varscan2
- HDAC2 | c.539A>G p.H180R | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs1562144936, COSV64038984; called by muse, mutect2
- HTR2A | c.526G>A p.A176T | Missense Mutation (SNP) | VAF 20/254 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1334203728, COSV66327556; called by muse, mutect2
- KCNMA1 | c.647A>G p.Q216R | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.794); catalogued as COSV54269898; called by muse, mutect2, varscan2
- MEIS2 | c.905C>A p.P302Q (on ENST00000561208 / NM_170675.5; = p.P289Q on NM_002399.3) | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54931676, COSV54941335; called by muse, mutect2
- RNF145 | c.53C>T p.P18L (on ENST00000424310 / NM_001199383.2; = p.P46L on NM_144726.2) | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50867519, COSV50869251; called by muse, mutect2
- VIT | c.1776C>A p.N592K (on ENST00000389975 / NM_001177969.1; = p.N607K on NM_053276.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101007597; called by muse, mutect2
- ZFHX4 | c.8192A>T p.D2731V | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99265288; called by muse, mutect2
- TMIGD1 | c.198C>T p.L66= | Silent (SNP) | VAF 6/92 reads (7%) | catalogued as COSV61028782, COSV61028997; called by muse, mutect2
